Gene-level copy-number profile of specimen HCM-SANG-0314-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0314-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0314-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1158274-1118-43e2-aa39-f5094294817d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0314-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/03812f05-0adb-4794-ae1b-b7d3c83f9be2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 30; copy number 2: 7,018; copy number 3: 19,042; copy number 4: 22,860; copy number 5: 3,697; copy number 6: 4,623; copy number 7: 1,623; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:112,546,973–112,642,483, 2 genes: AC137549.1, LINC02200.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–6): RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–6): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 30. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
